Somatic mutation profile of tumor specimen BA3185D (aliquot aq-BA3185D) from BEATAML1.0 case 2769, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.5 years (27,566 days).
Specimen BA3185D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d467254c-c764-4a4d-be14-a5783afcdcc1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3291D (Solid Tissue Normal), aliquot aq-BA3291D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7dabdc3-f05e-4fac-a32d-965ed86bff04

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.529C>T p.R177* (on ENST00000344691 / NM_001001890.3; = p.R204* on NM_001754.5) | Nonsense Mutation (SNP) | VAF 13/191 reads (7%) | catalogued as rs1569061768, CM992142, COSV55866185; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- RUNX1 | c.231dup p.H78Afs*33 (on ENST00000344691 / NM_001001890.3; = p.H105Afs*33 on NM_001754.5) | Frame Shift Ins (INS) | VAF 10/19 reads (53%) | called by mutect2, varscan2
- RUNX1 | c.230delinsGG p.T77Rfs*34 (on ENST00000344691 / NM_001001890.3; = p.T104Rfs*34 on NM_001754.5) | Frame Shift Ins (INS) | VAF 13/33 reads (39%) | called by mutect2*, pindel, varscan2*
